Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3DY, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3DY-01A (Primary Tumor).

[page 1 of 2]
Surgery Date

100-0-3

carcinoma, papillary and follicular 8340/3

Site: thyroid, NOS C73.9

lw
10/26/11

SPECIMENS:

- A. PRETRACHEAL LYMPH NODE
- B. LEFT PARATRACHEAL LYMPH NODE
- C. RIGHT PARATRACHEAL LYMPH NODE
- D. THYROID

DIAGNOSIS:

- A. PRETRACHEAL LYMPH NODE, EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- B. LEFT PARATRACHEAL LYMPH NODE, EXCISION:
- METASTATIC PAPILLARY THYROID CARCINOMA PRESENT IN ONE OF TWO LYMPH NODES (1/2).
- C. RIGHT PARATRACHEAL LYMPH NODE, EXCISION:
- METASTATIC PAPILLARY THYROID CARCINOMA PRESENT IN TWO OF TWO LYMPH NODES (2/2).
- D. THYROID, TOTAL THYROIDECTOMY:
- MULTIFOCAL PAPILLARY THYROID CARCINOMA IN RIGHT AND LEFT THYROID, LARGEST TUMOR FOCUS MEASURING 1.7 x 1.1 CM.
- CARCINOMA FOCALLY EXTENDING TO RIGHT PERI-THYROID SOFT TISSUE.
- ONE LYMPH NODE ATTACHED TO RIGHT THYROID, POSITIVE FOR METASTATIC CARCINOMA (1/1).
- SURGICAL RESECTION MARGINS, NEGATIVE FOR TUMOR.
- CHRONIC LYMPHOCYTIC THYROIDITIS.
- SEE TEMPLATE.

THYROID TEMPLATE

Specimen Type:	Total thyroidectomy
Tumor Site:	Right and left lobes
Tumor Focality:	Multifocal
Tumor Size (Largest nodule):	1.7 cm in greatest dimension, 1.1 x 0.9 cm in additional dimension (right); 1.0 x 1.0 cm (left); and 1 mm (right)
Histologic Type:	Papillary carcinoma: mixed papillary and follicular variant
Margins:	Uninvolved; distance to closest margin: <1 mm. in both right and left thyroid
Venous/Lymphatic Invasion:	Present
Additional Findings:	Chronic lymphocytic thyroiditis
Lymph Nodes:	Right and Left
Procedure:	Lymph nodes biopsy
Metastatic papillary thyroid carcinoma present in 1/2 left paratracheal lymph nodes, 2/2 right paratracheal lymph nodes, and 1/1 right peri-thyroid lymph node.	
One pretracheal lymph node, negative for tumor.	

Pathologic Stage: pT3 N1a Mx

SPECIMEN(S):

A. PRETRACHEAL LYMPH NODE B. LEFT PARATRACHEAL LYMPH NODE C. RIGHT PARATRACHEAL LYMPH NODE D. THYROID

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSB: Left paratracheal lymph node: Positive for metastatic thyroid carcinoma.

[page 2 of 2]
By Dr., called to Dr. at

GROSS DESCRIPTION:

A. PRETRACHEAL LYMPH NODE

Received in formalin and labeled as "pretracheal lymph node" is a piece of yellow-tan adipose tissue measuring 2.8x0.9x0.2cm containing 2 possible lymph nodes measuring 0.3 and 0.5cm. Submitted in toto in block A1.

B. LEFT PARATRACHEAL LYMPH NODE

Received fresh for frozen section and labeled "left paratracheal lymph node" are 2 lymph nodes in aggregate measuring 1.5x0.8x0.2cm. Touch preps are performed and the specimen is submitted in toto block FSB1.

C. RIGHT PARATRACHEAL LYMPH NODE

Received in formalin and labeled "right paratracheal lymph node" are 2 pink-tan lymph nodes measuring 0.2 and 0.3cm. Submitted in toto in block C1.

D. THYROID

Received fresh for possible tissue procurement and labeled "thyroid" is a 11.5gm thyroid gland. The right lobe is 5.0x2.3x0.5cm and the left lobe is 2.5x2.3x0.3cm. Right lobe is inked blue and the left lobe is inked yellow and the specimen is serially sectioned. Within the right lobe is a firm, tan mass, 1.7x1.1x0.9cm. In the left lobe is an area of diffuse white-tan discoloration measuring up to 0.9cm in greatest dimension. The remainder of the thyroid tissue has a meaty red-brown coloration. Sections are submitted for tissue procurement. Specimen is submitted in toto as follows:

D1-D2: mass from the right thyroid lobe

D3-D7: remainder of the tissue from the right lobe of thyroid

D8: isthmus

D9-D10: normal appearing left thyroid lobe

D11-D13: area of discoloration from left lobe

Gross Dictation:.

Microscopic/Diagnostic Dictation: , M.D., Pathologist

Final Review: , M.D., Pathologist.

Final: , M.D., Pathologist.

Source: NCI Genomic Data Commons file 69f8ce7e-9f81-404f-976c-d984bd803f84 (TCGA-E3-A3DY.C455F124-6CC8-4B9E-9CA6-68DF0A518639.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).